Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A50V, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A50V-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT:

ACCT #:

LOC:

REG DR:

AGE/SX:

ROOM:

DOB:

BED:

STATUS:

SPEC #:

RECD:

STATUS:

PERFORMED AT

COLL:

TIME IN FORMALIN:

hrs.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Colon polyps

Remarks:

Specimen(s): Right hemicolon

MICROSCOPIC DIAGNOSIS

COLON, RIGHT, RIGHT HEMICOLECTOMY:

- INVASIVE LOW-GRADE ADENOCARCINOMA OF CECUM/ILEOCECAL VALVE MEASURING 9 CM IN GREATEST DIMENSION
- TUMOR INVADES THROUGH MUSCLE WALL INTO SUBSEROSAL ADIPOSE TISSUE (pT3)
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- FOUR (4) OF 35 REGIONAL LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA WITH EXTRANODAL CAPSULAR EXTENSION PRESENT
- MARGINS NEGATIVE WITH CLOSEST MARGIN MESENTERIC (4.5 CM)
- APPENDIX WITH NO PATHOLOGIC DIAGNOSIS
- FEW SHALLOW DIVERTICULA

1CD-0-3

adenocarcinoma, NOS 8/40/3

Sitz: colon, cecum c18.0 ju 11/7/12

COMMENT(S)

SURGICAL PATHOLOGY CANCER CASE SUMMARY - APPROVED BY COLLEGE OF AMERICAN PATHOLOGISTS

SPECIMEN:

Terminal ileum, cecum, appendix, ascending colon

PROCEDURE:

Right hemicolectomy

TUMOR SITE:

Cecum, ileocecal valve

TUMOR SIZE:

Greatest dimension: 9 cm

MACROSCOPIC TUMOR PERFORATION:

Not identified

HISTOLOGIC TYPE:

Adenocarcinoma

HISTOLOGIC GRADE:

Low-grade

MICROSCOPIC TUMOR EXTENSION:

Tumor invades through the muscularis propria into the subserosal adipose tissue

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin:
4.5 cm, mesenteric/radial

Proximal margin: uninvolved by invasive carcinoma

Distal margin: uninvolved by invasive carcinoma

Circumferential margin: uninvolved by invasive carcinoma

No prior treatment

Not identified

Not identified

TREATMENT EFFECT:

LYMPH-VASCULAR INVASION:

PERINEURAL INVASION:

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE: [REDACTED]
RUN TIME: [REDACTED]
RUN USER: [REDACTED]

PAGE 2

Specimen Inquiry

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

COMMENT(S)

(Continued)

TUMOR DEPOSITS:

Not identified

PATHOLOGIC STAGING:

Primary tumor: pT3

Regional lymph nodes: pN2a

Number of lymph nodes examined: 35

Number of lymph nodes involved: 4

Distant metastasis: not applicable

GROSS DESCRIPTION:

Received fresh for tissue banking is a 25 cm segment of large bowel. The bowel is received with cecum and a 6.0 cm appendix. The colon is consistent with a right colectomy specimen and includes a 5.5 cm segment of small bowel. The cecum is indurated, and the serosa is focally puckered. The serosa is inked blue. The bowel is opened to have a linear 9.0 x 4.0 x at least 1.0 cm tumor mass. The mass fills and involves the cecum and extends to the ileocecal valve to be circumferential involving the ileocecal valve. The tumor diffusely extends to involve and focally extend through the bowel wall. There is an area of tattoo dye in the ascending colon. This area of tattoo dye is approximately 2.5 x 2.5 cm and is 6.0 cm from the ileocecal valve and at least 10 cm from the distal margin. The tumor is at least 15 cm from the distal margin. The mesenteric/fat margin is 4.5 cm. The remainder of the mucosa of the large bowel and small bowel are unremarkable with normal tan folds. There is a diverticular area of puckering in the distal segment of colon which is at least 2.5 cm from the distal margin. The surrounding adipose is sectioned to have multiple nodular lymph nodes. Both tumor and normal are sampled for tissue banking. The specimen is sampled as labeled:

- 1 - proximal margin
- 2 - distal margin
- 3 - mesenteric fat margin nearest tumor
- 4 - representative sections of appendix
- 5 - ileocecal valve
- 6-9 - sections of tumor with representative sections showing tumor to normal mucosa, associated underlying fat, inked serosa
- 10 - representative sections of normal bowel and bowel with submucosal tattoo dye
- 11 - sections of diverticular puckering and distal ascending colon
- 12 - whole lymph nodes
- 13 - one lymph node bisected
- 14 - whole lymph nodes
- 15 - whole lymph nodes
- 16 - whole lymph nodes
- 17 - whole lymph nodes and ? tumor implant
- 18 - two lymph nodes, each bisected

INTRAOPERATIVE CONSULTATION:

RIGHT HEMICOLON:

- GROSS SPECIMEN REVIEWED WITH [REDACTED] IN OPERATING ROOM. ONLY ONE LESION IS PRESENT AT THE ILEOCECAL VALVE. TATTOO PIGMENT IS PRESENT WITHIN THE MID ASCENDING COLON, 6 CM DISTAL TO THE ILEOCECAL VALVE TUMOR. NO SEPARATE LESION IS

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #:

PATIENT: 1

(continued)

INTRAOPERATIVE CONSULTATION: (Continued)

IDENTIFIED. THE TATTOO PIGMENT LIES 15 CM FROM THE DISTAL MARGIN. THE SPECIMEN IS PROCESSED FOR TISSUE BANKING.

PHOTO DOCUMENTATION

Image . Picture Copy Error
Image . Picture Copy Error

Signed ____ (signature on file) ____

** END OF REPORT **

HPVAA Discrepancy		☒

11/7/12

Source: NCI Genomic Data Commons file 249336b4-4a85-4e4f-a944-6c92728f63c6 (TCGA-NH-A50V.A745029F-98FE-44AA-8006-A06CEB09F560.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).